Somatic mutation profile of tumor specimen MP2PRT-PAUTJS-TMP1-A (aliquot MP2PRT-PAUTJS-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUTJS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,416 days).
Specimen MP2PRT-PAUTJS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 446d1da6-6159-428f-9068-c6cb4b232fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTJS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTJS-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaf51b09-4ab7-4e18-b736-7daaaddd5bfb

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 2, In Frame Ins 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.9686G>A p.R3229Q | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs372970766; called by muse, mutect2, varscan2
- DSCAM | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761826018, COSV101261377; called by muse, mutect2, varscan2
- EFHD2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); catalogued as rs1186418726; called by muse, varscan2
- NMUR1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 141/566 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs765171008, COSV100531817; called by muse, mutect2, varscan2
- OR5H15 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs548942009; called by muse, mutect2, varscan2
- PACSIN2 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 104/421 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs531993562; called by muse, mutect2, varscan2
- SH2B2 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 134/546 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV60828479; called by muse, mutect2, varscan2
- SLFN12L | c.634G>T p.E212* (on ENST00000260908 / NM_001363830.1; = p.E230* on NM_001195790.1) | Nonsense Mutation (SNP) | VAF 38/372 reads (10%) | catalogued as COSV53475520; called by muse, mutect2
- TAF11L13 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1445572219; called by muse, mutect2, varscan2
- VIT | c.865A>T p.N289Y (on ENST00000389975 / NM_001177969.1; = p.N304Y on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV64898083; called by muse, mutect2, varscan2
- ZFHX2 | c.4046C>T p.P1349L | Missense Mutation (SNP) | VAF 106/462 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1222531148; called by muse, mutect2, varscan2
- ZNF519 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.028); catalogued as rs147229950, COSV73913283; called by muse, mutect2, varscan2
- BFSP1 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MED15 | c.1859C>T p.P620L (on ENST00000263205 / NM_001003891.3; = p.P580L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/552 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MN1 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 69/663 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBBP8NL | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 24/610 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- RTL8A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 106/196 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TIMM8B | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 28/367 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2
- ZNF608 | c.3217_3218insGTGGGGTTCCTG p.P1072_A1073insGGVP | In Frame Ins (INS) | VAF 43/281 reads (15%) | called by mutect2, pindel, varscan2
- INSL6 | c.216C>G p.V72= | Silent (SNP) | VAF 92/334 reads (28%) | catalogued as rs755834086, COSV67563093; called by muse, mutect2, varscan2
- RBMXL3 | c.2892C>T p.R964= | Silent (SNP) | VAF 22/320 reads (7%) | catalogued as rs1194745381; called by muse, mutect2
- SLC12A8 | c.288G>A p.G96= | Silent (SNP) | VAF 144/517 reads (28%) | called by muse, mutect2, varscan2
- ZNF804A | c.2226A>G p.Q742= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- ZSCAN1 | c.582G>T p.A194= | Silent (SNP) | VAF 52/532 reads (10%) | catalogued as rs747742044, COSV56605398; called by muse, mutect2
- DST | c.4297-1488C>T | Intron (SNP) | VAF 19/305 reads (6%) | catalogued as rs369328276; ClinVar: uncertain significance; called by muse, mutect2
- RMDN2 | c.452+22121C>T | Intron (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
